Somatic mutation profile of tumor specimen MP2PRT-PAVFDB-TBP1-A (aliquot MP2PRT-PAVFDB-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVFDB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.7 years (3,176 days).
Specimen MP2PRT-PAVFDB-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e7267a9-8a16-495e-885d-8fb9dafd358e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVFDB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVFDB-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/910227a9-2b29-489e-98e2-1a5e333d42cd

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1210C>T p.R404* | Nonsense Mutation (SNP) | VAF 87/452 reads (19%) | catalogued as rs373145711, CM116006, COSV60102210; ClinVar: pathogenic; called by muse, varscan2
- ASXL1 | c.1281dup p.Q428Tfs*10 | Frame Shift Ins (INS) | VAF 117/545 reads (21%) | catalogued as rs886042532; ClinVar: uncertain significance; called by pindel, varscan2
- FAT3 | c.4895C>T p.T1632M | Missense Mutation (SNP) | VAF 32/420 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as rs748433498, COSV53194214; called by muse, mutect2
- KRT85 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 68/796 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV57736818; called by muse, mutect2
- MGAT4D | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs769732966; called by muse, mutect2, varscan2
- SMS | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 79/267 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs377476289, COSV101048253; called by muse, mutect2, varscan2
- ZEB2 | c.3113A>G p.H1038R | Missense Mutation (SNP) | VAF 52/370 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57953045; called by muse, mutect2, varscan2
- CLSPN | c.3035G>A p.S1012N | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, mutect2
- IGKV1D-42 | c.281C>A p.T94N | Missense Mutation (SNP) | VAF 96/374 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RRAS2 | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TMEM45B | c.333C>T p.H111= | Silent (SNP) | VAF 60/219 reads (27%) | catalogued as rs767679668; called by muse, mutect2, varscan2
